Gene-level copy-number profile of tumor specimen TCGA-EJ-5518-01A from TCGA case TCGA-EJ-5518, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.6 years (24,313 days).
Specimen TCGA-EJ-5518-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.a41df7d8-0129-45c2-9d65-8bfdeb365118.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EJ-5518-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/53305c5a-34ea-4a3f-908d-362bcd624b60

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 45; copy number 1: 8,478; copy number 2: 47,112; copy number 3: 4,033; copy number 4: 139; copy number 5: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EJ-5518-01A-01D-1574-01): tumor purity 0.53, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,258,885–147,517,875, 1 gene, copy number 5 (within-gene range 3–5): LINC00624.
- chr1:147,419,053–147,670,524, 7 genes, copy number 5 (within-gene range 2–5): OR13Z1P, Y_RNA, OR13Z2P, OR13Z3P, BCL9, AC242628.1, ACP6.
- chr1:188,508,538–188,695,111, 3 genes, copy number 5: AL929288.1, AL929288.2, RPS3AP9.

Autosomal genes at a single copy (total copy number 1): 6,143. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
